Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3J7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3J7-06A (Metastatic).

[page 1 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Enquiries :

REQUESTING DR :
VERIFIED BY

SPECIMEN DATE :
ACCESSION :

REPORTED BY

Reported by:

Previous

CLINICAL INFORMATION

Metastatic melanoma -> intransit met on back & palpable nodes in axilla.

OPERATION/NATURE OF SPEC

1. Wide excision (L) back. WEPC + (L) axillary clearance -> axillary contents
-> apical ?fat or node. Histopath.

MACROSCOPIC DESCRIPTION

Three specimens were received.

I. "Left axillary contents". A piece of fatty tissue, 140 x 130 x 50mm with an attached piece of skeletal muscle 85 x 37 x 33mm. The specimen was dissected for lymph nodes beginning at the end closest to the muscle where there is a suture attached. No lesions seen within the skeletal muscle.

- A. 1 lymph node (adjacent to suture).
- B. 1 lymph node.
- C&D. 1 lymph node.
- E&F. 1 lymph node.
- G&H. 1 lymph node.
- J. 1 lymph node.
- K. 1 lymph node.
- L. 1 lymph node.
- M. 1 lymph node.
- N. 1 lymph node.
- O. 1 lymph node.
- P. 1 lymph node.
- Q. Two sections through an obviously involved partly cystic node 30mm across.
- R. 1 lymph node.
- S. 1 lymph node.
- T. 1 lymph node.
- U. 1 lymph node.
- V. 1 lymph node.
- W&X. 1 lymph node.
- Y. 1 lymph node.

1CD-0-3

Melanoma, Nos 8720/3

Site: Subcutaneous, shoulder C49.1

hw 4/10/12

* Continued next page *

[page 2 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries :

REQUESTING DR :
Verified by :

SPECIMEN DATE
ACCESSION

MACROSCOPIC DESCRIPTION ...Cont'd

Z. 2 lymph nodes.
AA. 1 lymph node.
AB. ? 1 lymph node.

II. "Possible node apex left axilla". A piece of firm, fatty tissue 15 x 13 x 8mm. The specimen bisected and both halves embedded in one block. No definite lymphoid tissue seen.

III. "Left shoulder recurrent tumour". An ellipse of skin, 130 x 29 x 15mm. A circle is drawn on the skin and deep to this in the subcutaneous fat is a lobulated tan tumour nodule, 21 x 17mm. The nodule has been incised through the deep margin prior to receipt. The surgical margins were inked as accurately as possible. At one end of the skin ellipse is a longitudinal scar, 43mm in length, the centre of which is 7mm from the nearest margin. The tumour extends to within less than 1mm of the deep margin. It appears to be separate from the deep margin by a thin layer of fibrous tissue. Representative sections through the nodule embedded in blocks A to C. Two sections through the scar embedded in blocks D & E.

MICROSCOPIC DESCRIPTION

I. "Left axillary contents". Sections show a pleomorphic epithelioid cell tumour with focal necrosis that extensively replaces one node. No extracapsular spread seen.

A few atypical cells are present within the capsule and subcapsular sinus in one other node (M) which are S100 positive consistent with metastatic malignant melanoma (the cells are not present on slides stained with HMB45 and Melan A)

Immunostains of the large tumour mass show:

Positive: S100, HMB45 (focal), Melan A
Negative: Nil

No evidence of malignancy is seen in the remaining 23 lymph nodes.

II. "Possible node apex left axilla". Sections show a lymph node and adjacent adipose tissue. No evidence of malignancy is seen.

III. "Left shoulder recurrent tumour". Sections show skin with a subcutaneous nodule composed of nests of pleomorphic epithelioid cells consistent with malignant melanoma. The tumour is about 1mm clear of the deep margin. A dermal scar is also present.

* Continued next page *

[page 3 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Enquiries :

REQUESTING DR :
Verified by :

SPECIMEN DATE
ACCESSION

MICROSCOPIC DESCRIPTION ...Cont'd

DIAGNOSIS

- I. (L) axillary lymph nodes: METASTATIC MELANOMA IN 2 OF 25 NODES.
- II. (L) apical axillary lymph node: NO EVIDENCE OF MALIGNANCY.
- III. Skin of (L) shoulder: METASTATIC MELANOMA.

SNOMED CODES

lymph node - metastatic melanoma
Skin of shoulder - metastatic melanoma
Haematopathology resection

***** END OF ACCESSION *****

Source: NCI Genomic Data Commons file bf7f0b6a-26a2-4a0e-93bb-d011bc2c8ea3 (TCGA-EE-A3J7.F2479711-8EEC-44A5-877C-7804A631FCBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).